Somatic mutation profile of tumor specimen TCGA-B0-5697-01A (aliquot TCGA-B0-5697-01A-11D-1534-10) from TCGA case TCGA-B0-5697, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 50.6 years (18,486 days).
Specimen TCGA-B0-5697-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65bebf14-c82b-443c-8f0c-8c771fd2acdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5697-11A (Solid Tissue Normal), aliquot TCGA-B0-5697-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1154a13b-8166-4175-a878-5f9c9564dd66

The open-access MAF lists 54 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 34, Silent 11, Frame Shift Del 4, Nonsense Mutation 2, In Frame Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD4 | c.497T>C p.I166T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as rs145669133; called by muse, mutect2, varscan2
- ANK2 | c.5906C>T p.T1969I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.587); catalogued as rs148760530; called by muse, mutect2, varscan2
- BTNL8 | c.1319T>A p.L440* | Nonsense Mutation (SNP) | VAF 112/272 reads (41%) | catalogued as COSV51461760; called by muse, mutect2, varscan2
- CR1 | c.5077T>A p.C1693S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65462998; called by muse, mutect2, varscan2
- EGR1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV53518389; called by muse, mutect2
- ENPP2 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.878); catalogued as COSV50037745; called by muse, mutect2, varscan2
- FREM2 | c.2584G>A p.A862T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV54851861; called by muse, mutect2, varscan2
- GLB1 | c.1037A>C p.K346T | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56567871; called by muse, mutect2, varscan2
- GPR119 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52276567; called by muse, mutect2, varscan2
- GPR143 | c.549G>A p.R183= | Splice Region (SNP) | VAF 14/39 reads (36%) | catalogued as COSV66633159; called by muse, mutect2, varscan2
- HELLS | c.1852-2A>T p.X618_splice | Splice Site (SNP) | VAF 19/137 reads (14%) | catalogued as COSV53301174; called by muse, mutect2, varscan2
- HEY1 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.844); catalogued as rs201298116, COSV61233687; called by muse, mutect2, varscan2
- IQSEC2 | c.1112G>A p.R371H (on ENST00000642864 / NM_001111125.3; = p.R166H on NM_015075.2) | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1556864700, COSV64727990; called by muse, varscan2
- ISL2 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.806); catalogued as COSV51958461; called by muse, mutect2
- JRK | c.986A>T p.Q329L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1554635499, COSV70630448; called by muse, mutect2
- KCNH5 | c.294C>A p.Y98* | Nonsense Mutation (SNP) | VAF 26/199 reads (13%) | catalogued as COSV59777272; called by muse, mutect2, varscan2
- LRBA | c.6223G>C p.A2075P | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV63964552; called by muse, mutect2, varscan2
- LRRK1 | c.5365G>A p.V1789M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as rs536296948, COSV52625692; called by muse, mutect2, varscan2
- LRRTM3 | c.699C>A p.N233K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs760290602, COSV63671797; called by muse, mutect2, varscan2
- MIS18A | c.603A>G p.I201M | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.056); catalogued as COSV51589901; called by muse, mutect2, varscan2
- MT1G | c.170A>G p.K57R (on ENST00000379811 / NM_001301267.2; = p.K56R on NM_005950.3) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); catalogued as COSV60091565; called by muse, mutect2, varscan2
- MTOR | c.4388A>C p.Y1463S | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV63870743, COSV63878032; called by muse, mutect2, varscan2
- NCOA4 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1246273594; called by muse, mutect2, varscan2
- OR2T2 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs1274629943, COSV61618954, COSV61619014; called by muse, mutect2, varscan2
- OVCH2 | c.416T>C p.M139T | Missense Mutation (SNP) | VAF 65/374 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs531948527, COSV71953154; called by muse, mutect2, varscan2
- PCNX4 | c.2017G>T p.G673C (on ENST00000406854 / NM_001330177.2; = p.G439C on NM_022495.5) | Missense Mutation (SNP) | VAF 94/414 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58308027; called by muse, mutect2, varscan2
- PHF3 | c.4187A>G p.N1396S | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV50340485; called by muse, mutect2, varscan2
- PKHD1L1 | c.8608A>T p.T2870S | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as COSV65742717, COSV65752646; called by muse, mutect2, varscan2
- S1PR3 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs775020370, COSV63981329; called by muse, mutect2, varscan2
- SCMH1 | c.540C>A p.N180K (on ENST00000326197 / NM_001031694.2; = p.N133K on NM_012236.4) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58240023; called by muse, mutect2, varscan2
- SEC61A2 | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 17/598 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV53654918; called by muse, mutect2
- SERPINB5 | c.169G>C p.V57L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs766152603, COSV66976130; called by muse, mutect2
- SERPING1 | c.1408G>T p.V470F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV99558112; called by muse, varscan2
- SIGLEC12 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs773418381, COSV52464808; called by muse, mutect2, varscan2
- VPS39 | c.2482G>A p.E828K (on ENST00000348544 / NM_001301138.2; = p.E817K on NM_015289.5) | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as COSV58793216; called by muse, mutect2, varscan2
- WASL | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV56136137; called by muse, mutect2, varscan2
- ZBTB22 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99802508; called by muse, mutect2
- ZMYM5 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV61989925; called by muse, mutect2, varscan2
- ATAD2 | c.1086_1088dup p.S366dup | In Frame Ins (INS) | VAF 29/184 reads (16%) | called by mutect2, pindel, varscan2
- CNTRL | c.3672_3679del p.S1224Rfs*3 | Frame Shift Del (DEL) | VAF 27/192 reads (14%) | called by mutect2, pindel, varscan2
- DDO | c.593del p.P198Lfs*2 (on ENST00000368924 / NM_001368172.1; = p.P139Lfs*2 on NM_004032.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by pindel, varscan2
- DNMT3A | c.2515del p.S839Pfs*2 | Frame Shift Del (DEL) | VAF 82/276 reads (30%) | called by mutect2, pindel, varscan2
- TXLNA | c.1235_1237delinsCA p.K412Tfs*7 | Frame Shift Del (DEL) | VAF 28/193 reads (15%) | called by pindel, varscan2*
- DDO | c.585G>A p.K195= (on ENST00000368924 / NM_001368172.1; = p.K136= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV64469994; called by muse, varscan2
- DNAH2 | c.3597G>A p.E1199= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV66726930; called by muse, mutect2, varscan2
- KLF9 | c.477T>C p.H159= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV65808181; called by muse, varscan2
- KMO | c.378C>G p.P126= | Silent (SNP) | VAF 61/299 reads (20%) | catalogued as COSV63810606; called by muse, mutect2, varscan2
- PRKN | c.1269A>G p.V423= | Silent (SNP) | VAF 99/412 reads (24%) | catalogued as rs1330778122, COSV58276860; called by muse, mutect2, varscan2
- PTPN13 | c.3771T>A p.S1257= (on ENST00000411767 / NM_080683.3; = p.S1238= on NM_006264.3) | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV57417091; called by muse, mutect2, varscan2
- RBM25 | c.360A>G p.Q120= | Silent (SNP) | VAF 84/352 reads (24%) | catalogued as COSV56202800; called by muse, mutect2, varscan2
- RDM1 | c.624G>A p.K208= | Silent (SNP) | VAF 51/201 reads (25%) | catalogued as rs112692396; called by muse, mutect2, varscan2
- SEPTIN11 | c.906T>G p.L302= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV53584629; called by muse, mutect2, varscan2
- SLC1A7 | c.27G>A p.R9= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs267598645, COSV65196166; called by muse, mutect2, varscan2
- TRHR | c.945C>T p.I315= | Silent (SNP) | VAF 49/224 reads (22%) | catalogued as rs1489752478, COSV61236418; called by muse, mutect2, varscan2
